Somatic mutation profile of cancer-model specimen HCM-CSHL-0432-C20-85A (3D Organoid; aliquot HCM-CSHL-0432-C20-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-CSHL-0432-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-CSHL-0432-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52105f9f-f979-4b92-9815-c153b3765b7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0432-C20-10A (Blood Derived Normal), aliquot HCM-CSHL-0432-C20-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4714c861-8c7a-4bbd-87be-9113b841f374

The open-access MAF lists 106 somatic variants for this specimen: 70 protein-altering or splice-affecting, 29 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 29, Intron 5, Nonsense Mutation 5, Frame Shift Del 3, 5'Flank 2, Frame Shift Ins 2, In Frame Ins 1, In Frame Del 1, Translation Start Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4135G>T p.E1379* | Nonsense Mutation (SNP) | VAF 253/254 reads (100%) | hotspot (GDC flag); catalogued as rs121913326, COSV57320699, COSV57391553; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 170/170 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKS6 | c.2428G>A p.G810S | Missense Mutation (SNP) | VAF 116/238 reads (49%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as rs748782774; called by muse, mutect2, varscan2
- ANP32A | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 166/356 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1012536396; called by muse, mutect2, varscan2
- BRINP3 | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 103/203 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66531766; called by muse, mutect2, varscan2
- C10orf90 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 135/312 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs750247049, COSV52959603; called by muse, mutect2, varscan2
- CAMK2B | c.986C>T p.A329V | Missense Mutation (SNP) | VAF 170/354 reads (48%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.212); catalogued as rs1394172840; called by muse, mutect2, varscan2
- CAMK4 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV56670918; called by muse, mutect2, varscan2
- CCDC57 | c.2350C>T p.Q784* | Nonsense Mutation (SNP) | VAF 81/262 reads (31%) | catalogued as rs1479026062; called by muse, mutect2, varscan2
- CERK | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); catalogued as rs759596194; called by muse, varscan2
- CLIC4 | c.95T>C p.I32T | Missense Mutation (SNP) | VAF 104/208 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as rs1388318352; called by muse, mutect2, varscan2
- COL14A1 | c.5074C>T p.R1692* | Nonsense Mutation (SNP) | VAF 92/305 reads (30%) | catalogued as rs1381809857; called by muse, mutect2, varscan2
- DBX2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 265/543 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs929775800; called by muse, mutect2, varscan2
- DNALI1 | c.37A>C p.S13R | Missense Mutation (SNP) | VAF 149/275 reads (54%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1037396541; called by mutect2, varscan2
- EVC | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 134/275 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs766938849; called by muse, mutect2, varscan2
- FAM47C | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 362/365 reads (99%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs369396417, COSV63728600; called by muse, mutect2, varscan2
- FARP1 | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 175/373 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs778325187, COSV60330904; called by muse, mutect2, varscan2
- GEM | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 18/680 reads (3%) | catalogued as rs1011758304, COSV52598880; called by muse, mutect2
- GGCT | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 273/432 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371796444; called by muse, mutect2, varscan2
- GPRASP1 | c.2240C>A p.T747N | Missense Mutation (SNP) | VAF 158/310 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV64355511; called by muse, mutect2, varscan2
- HTR3D | c.739G>A p.D247N (on ENST00000382489 / NM_001163646.2; = p.D74N on NM_182537.3) | Missense Mutation (SNP) | VAF 186/340 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs145250740; called by muse, mutect2, varscan2
- HYDIN | c.14533C>T p.R4845W | Missense Mutation (SNP) | VAF 117/262 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748968493; called by muse, mutect2, varscan2
- INO80 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1466180067, COSV62739938; called by muse, mutect2, varscan2
- IRS1 | c.2389C>T p.R797C | Missense Mutation (SNP) | VAF 19/447 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs980309168, COSV59334810; called by muse, mutect2
- LRRK2 | c.4348G>A p.V1450I | Missense Mutation (SNP) | VAF 98/176 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.09); catalogued as rs111501952, CM147999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MOXD1 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 105/254 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs377603332; called by muse, mutect2, varscan2
- MSR1 | c.1147G>A p.V383I | Missense Mutation (SNP) | VAF 163/163 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.09); catalogued as rs766405850, COSV100027928, COSV50542362; called by muse, mutect2, varscan2
- MSRB3 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 78/169 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs199788089, COSV100378071; called by muse, mutect2, varscan2
- MYO3A | c.3574dup p.M1192Nfs*3 | Frame Shift Ins (INS) | VAF 96/217 reads (44%) | catalogued as rs757810767; called by mutect2, varscan2
- PCDHA7 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 252/465 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs782561322, COSV65341561, COSV65345338; called by muse, mutect2, varscan2
- PRR3 | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 137/291 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.223); catalogued as rs763365673, COSV64835153, COSV64835396; called by muse, mutect2, varscan2
- RAD54L2 | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs376693334; called by muse, mutect2, varscan2
- RGS12 | c.4195C>T p.R1399W (on ENST00000336727; = p.R751W on NM_198227.2) | Missense Mutation (SNP) | VAF 254/512 reads (50%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs777921323, COSV58750078; called by muse, mutect2, varscan2
- SCAPER | c.3293G>A p.R1098Q | Missense Mutation (SNP) | VAF 70/165 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs771454836; called by muse, mutect2, varscan2
- SCG2 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 131/280 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs149957287; called by muse, varscan2
- SIM1 | c.122C>G p.S41C | Missense Mutation (SNP) | VAF 139/325 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53494370, COSV99492671; called by muse, mutect2, varscan2
- SPN | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 192/411 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0.09); catalogued as rs770048371, COSV64070256; called by muse, mutect2, varscan2
- TCF7L2 | c.701C>T p.P234L (on ENST00000355995 / NM_001367943.1; = p.P211L on NM_030756.5) | Missense Mutation (SNP) | VAF 157/294 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.183); catalogued as rs1465566182, COSV53352252; called by muse, mutect2, varscan2
- TNXB | c.6055C>T p.R2019C (on ENST00000647633; = p.R1772C on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 130/303 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.962); catalogued as rs540179287, COSV64488127; called by muse, mutect2, varscan2
- UNC79 | c.6954G>A p.M2318I (on ENST00000393151 / NM_001346218.2; = p.M2141I on NM_020818.5) | Missense Mutation (SNP) | VAF 133/274 reads (49%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as COSV99825235; called by muse, mutect2, varscan2
- WDR70 | c.1150G>A p.V384M | Missense Mutation (SNP) | VAF 113/341 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as rs201460694, COSV54270853, COSV54279822; called by muse, mutect2, varscan2
- ZBTB10 | c.1576G>A p.G526S | Missense Mutation (SNP) | VAF 127/387 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs543566367, COSV66948407; called by muse, mutect2, varscan2
- ZNF775 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 246/525 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100301504; called by muse, mutect2, varscan2
- ZNF835 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 172/350 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101606434, COSV73379655; called by muse, mutect2, varscan2
- ADAMTS2 | c.800_802del p.N267del | In Frame Del (DEL) | VAF 152/365 reads (42%) | called by pindel, varscan2
- APP | c.2313G>C p.*771Yext*26 | Nonstop Mutation (SNP) | VAF 59/180 reads (33%) | called by muse, mutect2, varscan2
- BRPF3 | c.1514A>G p.N505S | Missense Mutation (SNP) | VAF 197/390 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DISP2 | c.1426C>T p.L476F | Missense Mutation (SNP) | VAF 159/342 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DPYD | c.602G>C p.S201T | Missense Mutation (SNP) | VAF 196/334 reads (59%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDEM3 | c.762A>C p.K254N | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2
- ESPN | c.3263G>A p.R1088H | Missense Mutation (SNP) | VAF 349/628 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- FSIP2 | c.2072dup p.N691Kfs*5 | Frame Shift Ins (INS) | VAF 75/189 reads (40%) | called by mutect2, pindel, varscan2
- GALNT17 | c.1021G>T p.G341C | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INAFM2 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 347/735 reads (47%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAPKBP1 | c.2428A>G p.T810A (on ENST00000456763 / NM_001128608.2; = p.T804A on NM_014994.3) | Missense Mutation (SNP) | VAF 118/236 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSI2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 144/435 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR2B11 | c.93_94del p.F32Cfs*152 | Frame Shift Del (DEL) | VAF 87/246 reads (35%) | called by pindel, varscan2
- OR5D13 | c.530_533del p.N177Ifs*8 | Frame Shift Del (DEL) | VAF 98/225 reads (44%) | called by pindel, varscan2
- PPP1R3A | c.2632G>T p.E878* | Nonsense Mutation (SNP) | VAF 93/205 reads (45%) | called by muse, mutect2, varscan2
- PRR32 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 190/379 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- SBK1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 288/468 reads (62%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- SCN7A | c.2327A>T p.D776V | Missense Mutation (SNP) | VAF 110/230 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- SWAP70 | c.364T>A p.F122I | Missense Mutation (SNP) | VAF 94/202 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- TAS1R2 | c.1370_1378dup p.R457_Q459dup | In Frame Ins (INS) | VAF 136/324 reads (42%) | called by mutect2, varscan2
- TBCK | c.2403T>A p.N801K (on ENST00000273980 / NM_001163436.4; = p.N738K on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TIAM1 | c.1976T>C p.V659A | Missense Mutation (SNP) | VAF 87/192 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- TPR | c.75del p.E26Kfs*14 | Frame Shift Del (DEL) | VAF 163/422 reads (39%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.8964A>C p.K2988N | Missense Mutation (SNP) | VAF 120/427 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF264 | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 116/257 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2
- ZNF727 | c.1451A>T p.N484I | Missense Mutation (SNP) | VAF 93/195 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAR1 | c.336C>T p.D112= | Silent (SNP) | VAF 253/502 reads (50%) | called by muse, mutect2, varscan2
- BPIFB6 | c.1167C>T p.S389= | Silent (SNP) | VAF 153/500 reads (31%) | called by muse, mutect2, varscan2
- BSND | c.9C>T p.D3= | Silent (SNP) | VAF 131/260 reads (50%) | catalogued as rs141111550, COSV64871340; called by muse, mutect2, varscan2
- CDH6 | c.1212C>T p.S404= | Silent (SNP) | VAF 193/318 reads (61%) | catalogued as rs147614751; called by muse, mutect2, varscan2
- CPSF6 | c.489C>T p.F163= | Silent (SNP) | VAF 88/206 reads (43%) | called by muse, mutect2, varscan2
- DHRS7B | c.291C>T p.T97= | Silent (SNP) | VAF 127/127 reads (100%) | catalogued as rs1235269467; called by muse, mutect2, varscan2
- DRC7 | c.1800G>A p.A600= | Silent (SNP) | VAF 16/392 reads (4%) | catalogued as rs1469146186, COSV100395401; called by muse, mutect2
- FAM47A | c.42C>A p.G14= | Silent (SNP) | VAF 133/307 reads (43%) | called by muse, mutect2, varscan2
- GRB7 | c.564C>T p.Y188= | Silent (SNP) | VAF 103/529 reads (19%) | catalogued as rs377657100; called by muse, mutect2, varscan2
- KRT12 | c.1062C>T p.N354= | Silent (SNP) | VAF 151/509 reads (30%) | called by muse, mutect2, varscan2
- LMLN | c.324C>T p.L108= | Silent (SNP) | VAF 49/131 reads (37%) | called by muse, mutect2, varscan2
- LTF | c.84C>T p.C28= | Silent (SNP) | VAF 136/136 reads (100%) | catalogued as rs777783348; called by muse, mutect2, varscan2
- MAGEB1 | c.906C>T p.S302= | Silent (SNP) | VAF 76/384 reads (20%) | called by muse, mutect2, varscan2
- MYO16 | c.4737G>A p.P1579= | Silent (SNP) | VAF 146/278 reads (53%) | called by muse, varscan2
- NOM1 | c.1611C>T p.S537= | Silent (SNP) | VAF 100/194 reads (52%) | catalogued as rs763316286; called by muse, mutect2, varscan2
- NRXN2 | c.2598G>A p.T866= | Silent (SNP) | VAF 199/428 reads (46%) | catalogued as rs746911445; called by muse, mutect2, varscan2
- PC | c.1110C>T p.N370= | Silent (SNP) | VAF 255/543 reads (47%) | catalogued as rs776429910, COSV63078986; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB7 | c.1971G>A p.T657= | Silent (SNP) | VAF 297/674 reads (44%) | catalogued as rs782733977; called by muse, mutect2, varscan2
- PDZD2 | c.18C>T p.D6= | Silent (SNP) | VAF 148/444 reads (33%) | catalogued as rs769354573; called by muse, mutect2, varscan2
- PIEZO2 | c.5766G>A p.S1922= | Silent (SNP) | VAF 166/338 reads (49%) | catalogued as rs767891927; called by muse, mutect2, varscan2
- PLD5 | c.1104A>G p.R368= (on ENST00000442594; = p.R306= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/198 reads (48%) | called by muse, mutect2, varscan2
- PRF1 | c.1065G>A p.P355= | Silent (SNP) | VAF 200/449 reads (45%) | catalogued as rs758932748, COSV64614421; called by muse, mutect2, varscan2
- SHCBP1L | c.183G>A p.A61= | Silent (SNP) | VAF 292/622 reads (47%) | called by muse, mutect2, varscan2
- SLC6A3 | c.1677G>A p.A559= | Silent (SNP) | VAF 230/800 reads (29%) | catalogued as rs767241571, COSV54361396; called by muse, varscan2
- TLX2 | c.180C>T p.Y60= | Silent (SNP) | VAF 81/587 reads (14%) | called by muse, mutect2, varscan2
- TUBA3C | c.309C>T p.Y103= | Silent (SNP) | VAF 108/270 reads (40%) | catalogued as rs114178008, COSV67139668; called by muse, mutect2, varscan2
- ZNF592 | c.771G>A p.G257= | Silent (SNP) | VAF 19/439 reads (4%) | catalogued as rs989833841; called by muse, mutect2
- ZNF737 | c.1293C>A p.G431= | Silent (SNP) | VAF 87/199 reads (44%) | called by muse, mutect2, varscan2
- ZNF99 | c.1092T>C p.T364= | Silent (SNP) | VAF 115/223 reads (52%) | catalogued as COSV101233783; called by muse, mutect2, varscan2
- C2orf16 | chr2:27572823 C>A | 5'Flank (SNP) | VAF 127/286 reads (44%) | called by muse, mutect2, varscan2
- CDC14B | c.161-1298C>G | Intron (SNP) | VAF 142/356 reads (40%) | catalogued as rs771627507; called by mutect2, varscan2
- CRYBG2 | chr1:26354705 G>A | 5'Flank (SNP) | VAF 234/465 reads (50%) | called by muse, mutect2, varscan2
- GRIA4 | c.2295-5891G>T | Intron (SNP) | VAF 41/102 reads (40%) | catalogued as rs774816694, COSV56882997; called by muse, mutect2, varscan2
- HINT1 | c.216+161C>T | Intron (SNP) | VAF 250/250 reads (100%) | catalogued as rs746686410; called by muse, mutect2, varscan2
- ST6GAL2 | c.1319-6264A>C | Intron (SNP) | VAF 20/264 reads (8%) | called by muse, mutect2
- SYNE1 | c.310-468G>A | Intron (SNP) | VAF 58/125 reads (46%) | catalogued as rs143635963, COSV55078667; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
